Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A19L, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A19L-06A (Metastatic).

ICD-0-3

10/15/10

Melanoma, NOS 8720/3

lw

PATIENT HISTORY:

The patient is a year-old male with metastatic melanoma

Site code: groin, soft tissue C49.5

PRE-OP DIAGNOSIS: Metastatic melanoma

POST-OP DIAGNOSIS: Same

PROCEDURE: Right groin dissection

**FINAL DIAGNOSIS:****PART 1: SOFT TISSUE, RETROPERITONEAL, RIGHT GROIN, DISSECTION -**

- A. TWO (2) LYMPH NODES WITH METASTATIC MELANOMA, ONE WITH EXTRACAPSULAR SPREAD (see comment).
- B. FOREIGN BODY GIANT CELL REACTION.

PART 2: SOFT TISSUE, RIGHT SUPERFICIAL GROIN, DISSECTION -

TWO (2) LYMPH NODES WITH METASTATIC MELANOMA AND FOCAL EXTRACAPSULAR SPREAD.

COMMENT:

Immunostains were performed and the tumor cells are immunoreactive for S100 protein and HMB45 and negative for cytokeratin (AE1/3), supporting melanoma.

Primary Tumor Discrepancy		☒
HPA's Discrepancy		☒

Source: NCI Genomic Data Commons file aadf09cc-42ed-4726-b0bd-be1d83a036ad (TCGA-ER-A19L.08B5D63E-87BC-4AA3-909B-36DF82127712.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).